Surgical pathology report (de-identified scan), TCGA case TCGA-15-0742, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Mayo Clinic - Rochester, specimen TCGA-15-0742-01A (Primary Tumor).

#

TCGA 15-0742-01A
TSI

Final Diagnosis:

Brain, left parieto-occipital mass, biopsy: Grade 4 (of 4) fibrillary astrocytoma (WHO, glioblastoma).

Signature on File

Tissue Description:

A1 A2 A3 B1 B2 B3 B4 B5 B6

Tissue from brain; left parieto-occipital region (No. 1--aggregating 3.2 x 2.2 x 0.3 cm, No. 2--5.2 x 2.4 x 0.7 cm)

Preliminary Frozen Section Consultation:

Brain, left parieto-occipital mass, biopsy: Astrocytoma, favor small cell type, at least intermediate grade. Hold for final typing and grading.

Source: NCI Genomic Data Commons file 54e09702-dc60-464e-b237-89f0127e2681 (TCGA-15-0742.E9FC50D8-86A1-451D-8B2D-CAA8729A1BF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).